Surgical pathology report (de-identified scan), TCGA case TCGA-GS-A9TV, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Fundacio Clinic per a la Recerca Biomedica, specimen TCGA-GS-A9TV-01A (Primary Tumor).

CERVICAL LEFT LYMPH NODE:

Lymph node of 2 x 1,2 x 0,6 cm. The cut surface is whitish and homogeneous.

CERVICAL LYMPH NODE, EXCISION:

- PRIMARY MEDIASTINAL DIFFUSE LARGE B CELL LYMPHOMA

Histological sections show a lymph node with a proliferation of atypical large cells forming nodules which are separated by some fibrosis bands. The neoplastic cells have immunoblastic and Reed-Sternberg morphology, forming clusters and extend to the perinodal adipose tissue.

The large cells are positive for CD20, PAX5, and partially for CD30 and CD23, and are negative for CD15. Several reactive T-cells are observed (CD3+ CD5+). The Ki67 proliferation index is 40%. The in situ hybridization for the Epstein-Barr virus (EBER) has been negative.

*ICD O-3
Lymphoma, diffuse large B cell
9680/3
Site Lymph node
0.77.0
JCO 3/31/14*

Source: NCI Genomic Data Commons file 1975e90f-3405-4bc2-87c1-ec974d1d0f63 (TCGA-GS-A9TV.2197BDCD-266C-4256-A18A-D0E8EAA63518.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).